Somatic mutation profile of tumor specimen 0E0YCR from CCDI case PBCVFP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female.
Specimen 0E0YCR: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 73bcf032-59ff-4bb9-93b9-350eeec4cb8a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0E0YD1 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aeb0ec93-37ee-47c0-988a-d6f8e30cce92

The open-access MAF lists 44 somatic variants for this specimen: 34 protein-altering or splice-affecting, 5 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 5, Intron 3, Nonsense Mutation 2, 3'Flank 1, Frame Shift Ins 1, Splice Region 1, Frame Shift Del 1, Splice Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1394G>A p.R465H (on ENST00000281708 / NM_001349798.2; = p.R385H on NM_018315.5) | Missense Mutation (SNP) | VAF 61/337 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519895, COSV55891746, COSV55897262, COSV55941157; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PPP2R1A | c.548G>A p.R183Q | Missense Mutation (SNP) | VAF 143/305 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs1057519947, COSV59042211, COSV59042295; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PRKAR1A | c.638C>A p.A213D | Missense Mutation (SNP) | VAF 78/527 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs281864786, CM081759, COSV62235955; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ARMCX1 | c.647G>A p.R216Q | Missense Mutation (SNP) | VAF 168/357 reads (47%) | SIFT tolerated (0.39); PolyPhen benign (0.402); catalogued as rs781958602; called by muse, mutect2, varscan2
- ARR3 | c.553C>A p.R185S | Missense Mutation (SNP) | VAF 150/319 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.127); catalogued as COSV52103500; called by muse, mutect2, varscan2
- CCDC57 | c.2128C>T p.R710W | Missense Mutation (SNP) | VAF 117/228 reads (51%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as rs1200043412; called by muse, mutect2, varscan2
- CPE | c.890G>A p.R297Q | Missense Mutation (SNP) | VAF 70/420 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.297); catalogued as rs541147146, COSV68580878; called by muse, mutect2, varscan2
- CYP2F1 | c.220C>T p.R74W | Missense Mutation (SNP) | VAF 114/265 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); catalogued as rs762195176, COSV58527177; called by muse, mutect2, varscan2
- DDX3X | c.840G>T p.Q280H (on ENST00000399959; = p.Q281H on NM_001356.5) | Missense Mutation (SNP) | VAF 146/333 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67863407, COSV67864668; called by muse, mutect2, varscan2
- FAM53A | c.632C>T p.A211V | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.242); catalogued as rs768797962; called by muse, mutect2, varscan2
- GPR55 | c.551C>T p.P184L | Missense Mutation (SNP) | VAF 138/297 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.432); catalogued as rs748482833, COSV67406983; called by muse, mutect2, varscan2
- KDM6A | c.1194+1G>T p.X398_splice | Splice Site (SNP) | VAF 85/316 reads (27%) | catalogued as COSV100937766; called by muse, mutect2, varscan2
- KIF2B | c.959C>T p.T320M | Missense Mutation (SNP) | VAF 37/404 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.501); catalogued as rs368097093, COSV52126688; called by muse, mutect2
- NFAT5 | c.1228C>T p.R410C | Missense Mutation (SNP) | VAF 166/389 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.237); catalogued as rs780672965; called by muse, mutect2, varscan2
- NUP133 | c.2393G>A p.R798Q | Missense Mutation (SNP) | VAF 171/394 reads (43%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.938); catalogued as rs753547351, COSV54568158, COSV99772635; called by muse, mutect2, varscan2
- PCDHGB2 | c.1738C>T p.R580C | Missense Mutation (SNP) | VAF 54/162 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs1226240896, COSV53912756; called by muse, mutect2, varscan2
- PRKAR1A | c.728G>A p.R243Q | Missense Mutation (SNP) | VAF 130/484 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV62235154; called by muse, mutect2, varscan2
- RCAN2 | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 85/355 reads (24%) | SIFT tolerated (0.59); PolyPhen benign (0.017); catalogued as rs1284035363, COSV57815056; called by muse, mutect2, varscan2
- STK32C | c.996C>T p.L332= | Splice Region (SNP) | VAF 36/195 reads (18%) | catalogued as rs369049317; called by muse, mutect2, varscan2
- SUPT20HL2 | c.1108C>T p.R370C | Missense Mutation (SNP) | VAF 27/181 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs1447804136; called by mutect2, varscan2
- TRPC5 | c.1534C>T p.R512C | Missense Mutation (SNP) | VAF 76/467 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs747130444, COSV53286728; called by muse, mutect2, varscan2
- USP6 | c.481C>T p.R161* | Nonsense Mutation (SNP) | VAF 75/202 reads (37%) | catalogued as rs778097103, COSV51495748; called by muse, mutect2, varscan2
- XCR1 | c.646C>T p.R216C | Missense Mutation (SNP) | VAF 88/168 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs779703839, COSV58569048; called by muse, mutect2, varscan2
- ALDH8A1 | c.237G>T p.L79F | Missense Mutation (SNP) | VAF 149/346 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- CCDC77 | c.1013G>T p.S338I | Missense Mutation (SNP) | VAF 38/302 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CDH22 | c.211G>A p.V71M | Missense Mutation (SNP) | VAF 29/172 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- DSP | c.7248dup p.D2417* | Frame Shift Ins (INS) | VAF 56/210 reads (27%) | called by mutect2, varscan2
- GPR3 | c.530G>T p.C177F | Missense Mutation (SNP) | VAF 32/189 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GSE1 | c.3463G>T p.E1155* | Nonsense Mutation (SNP) | VAF 49/314 reads (16%) | called by muse, mutect2, varscan2
- KIF7 | c.3037G>A p.E1013K | Missense Mutation (SNP) | VAF 68/123 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- PDE4A | c.1922C>G p.S641C (on ENST00000380702 / NM_001111307.2; = p.S402C on NM_006202.3) | Missense Mutation (SNP) | VAF 70/154 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.471); called by muse, mutect2, varscan2
- PXDNL | c.3557A>G p.K1186R | Missense Mutation (SNP) | VAF 76/568 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2
- SUZ12 | c.1694del p.Y565Ffs*17 | Frame Shift Del (DEL) | VAF 186/406 reads (46%) | called by mutect2, varscan2
- ZNF697 | c.607G>T p.A203S | Missense Mutation (SNP) | VAF 70/147 reads (48%) | SIFT tolerated (0.68); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- CD5 | c.927G>A p.S309= | Silent (SNP) | VAF 45/148 reads (30%) | catalogued as rs754369294; called by muse, mutect2, varscan2
- ELOA | c.2085G>A p.V695= | Silent (SNP) | VAF 62/496 reads (13%) | called by muse, mutect2, varscan2
- GMPR | c.198G>C p.V66= | Silent (SNP) | VAF 40/409 reads (10%) | catalogued as COSV52473537; called by muse, mutect2
- RNF215 | c.108G>A p.L36= | Silent (SNP) | VAF 8/62 reads (13%) | called by muse, mutect2, varscan2
- SEMA6C | c.2712G>A p.K904= | Silent (SNP) | VAF 25/137 reads (18%) | catalogued as rs1313878157; called by muse, mutect2, varscan2
- GRM6 | c.1500+15C>T | Intron (SNP) | VAF 51/169 reads (30%) | catalogued as rs376394600; called by muse, mutect2, varscan2
- HARS1 | chr5:140673480 C>T | 3'Flank (SNP) | VAF 71/141 reads (50%) | called by muse, mutect2, varscan2
- PHF8 | c.-31G>A | 5'UTR (SNP) | VAF 34/236 reads (14%) | called by muse, mutect2, varscan2
- PNCK | c.-2-184G>A | Intron (SNP) | VAF 60/155 reads (39%) | catalogued as COSV61745356; called by muse, mutect2, varscan2
- TSC2 | c.1362-74C>T | Intron (SNP) | VAF 29/65 reads (45%) | catalogued as rs1411766462; called by muse, mutect2, varscan2
